Gene-level copy-number profile of tumor specimen TCGA-ZN-A9VQ-01A from TCGA case TCGA-ZN-A9VQ, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.4 years (22,443 days).
Specimen TCGA-ZN-A9VQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.dd85d29b-5883-4292-849a-8706698ff32b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZN-A9VQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5bd3b673-cff8-4dab-9b06-5f42872fbbbc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 8,469; copy number 2: 48,723; copy number 3: 2,567.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZN-A9VQ-01A-11D-A39Q-01): tumor purity 0.94, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,682,662, 25 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr22:21,919,425–22,215,270, 32 genes (within-gene range 0–1): PPM1F, PPM1F-AS1, TOP3B, PRAMENP, IGLVI-70, IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,088. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
